Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A0JD, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A0JD-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis & History:

Left breast lump. FNA adenocarcinoma; core biopsy IFDC.

Specimens Submitted:

- 1: SP: Sentinel node #1, level one, left axilla (fs)
- 2: SP: Sentinel node #2, level one, left axilla (fs)
- 3: SP: Left breast
- 4: SP: Levels I and II left axillary contents
- 5: SP: Levels III and IV left axillary contents

DIAGNOSIS:

- 1) LYMPH NODES, SENTINEL #1, LEVEL I, LEFT AXILLA; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 2) LYMPH NODES, SENTINEL #2, LEVEL I, LEFT AXILLA; EXCISION:
- ONE OF ONE LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA (1/1).
- EXTRANODAL EXTENSION IS NOT PRESENT.
- 3) BREAST, LEFT; MASTECTOMY:
- INVASIVE DUCTAL CARCINOMA, NOS TYPE, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE III/III (MARKED VARIATION IN SIZE AND SHAPE), MEASURING 6 CM IN LARGEST DIMENSION GROSSLY.
- THE INVASIVE CARCINOMA IS LOCATED IN THE UPPER OUTER QUADRANT.
- NO INVOLVEMENT OF THE NIPPLE BY CARCINOMA IS IDENTIFIED.
- CALCIFICATIONS ARE PRESENT FOCALLY IN BENIGN BREAST PARENCHYMA.
- VASCULAR INVASION IS PRESENT.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY INVASIVE CARCINOMA IS IDENTIFIED.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE ATTACHED SKELETAL MUSCLE IS NEGATIVE FOR TUMOR.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS FLORID PAPILLOMATOSIS OF THE NIPPLE, BIOPSY SITE CHANGES, FIBROCYSTIC CHANGES, AND SCLEROSING ADENOSIS.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF POSITIVE LYMPH NODES IN RELATION TO THE TOTAL NUMBER OF LYMPH NODES EXAMINED): 2/4.
THERE IS NO EXTRANODAL EXTENSION OF CARCINOMA.
- ONE BENIGN INTRAMAMMARY LYMPH NODE (0/1).
- 4) LYMPH NODES, LEFT AXILLARY, LEVELS I AND II; EXCISION:
- EIGHT BENIGN LYMPH NODES (0/10).

** Continued on next page **

1C0-0-3

carcinoma, infiltrating duct, nos 8500/3
site: breast, nos 050.9 lw 10/22/11

[page 2 of 5]
- 5) LYMPH NODES, LEFT AXILLARY, LEVELS II AND III; EXCISION:
- NINE BENIGN LYMPH NODES (0/9).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	ER-C	
	PR-C	
	HER2-C	
	NEG CONT	
	IMM RECUT	
	NEG-HER2	

Gross Description:

- 1) The specimen is received fresh for frozen section, labeled "Sentinel node #1, level 1, left axilla". It consists of two lymph nodes measuring 1.0 and 0.5 cm. They are bisected and entirely frozen.

Summary of Sections:

FSC - Frozen section control

- 2) The specimen is received fresh for frozen section, labeled "Sentinel node #2, level 1, left axilla". It consists of one large lymph node, measuring 2.5 cm. The specimen is bisected and submitted in two cassettes.

Summary of Sections:

FSCA - Frozen section control A
FSCB - Frozen section control B

- 3) The specimen is received fresh, labeled "Left breast. Stitch marks axillary tail". It consists of a 34 x 22 x 6 cm mastectomy with a 30 x 12 cm ellipse of skin and a 1.5 cm everted nipple. A mass is palpable in the 12-3:00 position and the axillary tail is designated by a long black suture. The specimen is serially sectioned, revealing a 6.0 x 5.0 x 2.8 cm

** Continued on next page **

[page 3 of 5]
----- Page 3 of 5
gray-white, ill-defined mass, grossly 2 cm from the deep margin. Multiple lymph nodes are identified in the axillary tail, ranging from 0.3 to 3.5 cm. A single intramammary lymph node is identified. All lymph nodes are submitted. TPS is submitted.

Summary of Sections:

N - Nipple
DM - Deep margin
MASS - Multiple sections of the mass
UOQ - Representative upper outer quadrant
LOQ - Representative lower outer quadrant
UIQ - Representative upper inner quadrant
LIQ - Representative lower inner quadrant
SK - Representative skin
IMLN - Single intramammary lymph node
LN - Multiple lymph nodes
BLN - Bisected lymph node
SSLN - Largest serially sectioned lymph node

4) The specimen is received in formalin, labeled "Levels 1 and 2, left axillary contents". It consists of an 11 x 7 x 2 cm lobulated portion of fibrofatty tissue, with palpable lymph nodes ranging in size from 0.5 to 1.4 cm. A portion of a grossly positive lymph node is submitted for TPS. All lymph nodes are submitted.

Summary of Sections:

LN - Single lymph node per cassette

5) The specimen is received in formalin, labeled "Levels 2 and 3 left axillary contents". It consists of a 3.0 x 2.0 x 1.5 cm lobulated, fatty tissue fragment with palpable lymph nodes. All lymph nodes are submitted.

Summary of Sections:

LN - Lymph nodes

3

Summary of Sections:

Part 1: SP: Sentinel node #1, level one, left axilla (fs)

Block	Sect.	Site	PCs
1	fsc		1

Part 2: SP: Sentinel node #2, level one, left axilla (fs)

Block	Sect.	Site	PCs
1	fsca		1

** Continued on next page **

[page 4 of 5]
1

1

Part 3: SP: Left breast

Block	Sect. Site	PCs
1	bln	1
1	dm	1
1	imln	1
2	liq	2
4	ln	4
2	loq	2
4	mass	4
1	n	1
1	sk	1
4	ssln	4
2	uiq	2
2	uoq	2

Part 4: SP: Levels I and II left axillary contents

Block	Sect. Site	PCs
10	ln	10
1	tpsln	1

Part 5: SP: Levels II and III left axillary contents

Block	Sect. Site	PCs
4	ln	4

Procedures/Addenda:

Addendum

Date Ordered:

Date Complete:

Date Reported

Status: Signed Out
By:

4

Addendum Diagnosis

ADDENDUM

SITE: LEFT BREAST
PART #3.

ER: 90% OF NUCLEAR STAINING WITH MODERATE INTENSITY.
PR: 40% OF NUCLEAR STAINING WITH MODERATE INTENSITY.
HER2/NEU (HERCEPT): NEGATIVE (STAINING INTENSITY OF 1+).

MD

** Continued on next page **

[page 5 of 5]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN (0/2).
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: METASTATIC CARCINOMA IN ONE LYMPH NODE
(1/1).
PERMANENT DIAGNOSIS: SAME.

MD

5

** End of Report **

Source: NCI Genomic Data Commons file 53958540-2b60-48ab-92c8-6db55050a933 (TCGA-AO-A0JD.E8A43FF3-3D98-45EE-9567-6EED4DA38274.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).